TCGA case TCGA-2G-AAG4 — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/83a7e7dc-1fd2-49b2-a788-8219da2cb76a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 24 years; Year of birth: 1984; Vital status: Alive.

Diagnoses (4)
1. Mixed germ cell tumor (the primary disease): ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 24.1 years (8,795 days); Year of diagnosis: 2008; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IA; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,467 days (6.8 years); Ajcc serum tumor markers: S1.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: Yes; Timepoint category: Post Adjuvant Therapy.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 157 days; Days to treatment end: 213 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Ifosfamide + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 368 days (1.0 years); Days to treatment end: 442 days (1.2 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Mixed germ cell tumor), site: Intra-abdominal lymph nodes. Age at diagnosis: 24.5 years (8,951 days); Days to diagnosis: 156 days; Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Mixed germ cell tumor), site: Intra-abdominal lymph nodes. Age at diagnosis: 27.7 years (10,131 days); Days to diagnosis: 1,336 days (3.7 years); Prior treatment: Yes.
4. Recurrence of diagnosis 1 (Mixed germ cell tumor), site: Intra-abdominal lymph nodes. Age at diagnosis: 28.1 years (10,253 days); Days to diagnosis: 1,458 days (4.0 years); Prior treatment: Yes.

Follow-up (7 entries)
- Day 156 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 156 days.
- Day 367 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 367 days (1.0 years).
- Day 1,336 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 1,336 days (3.7 years).
- Day 1,458 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 1,458 days (4.0 years).
- Days to follow up: 2,097 days (5.7 years); Disease response: Tumor Free.
- Days to follow up: 2,467 days (6.8 years); Disease response: Tumor Free.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -3: Lactate Dehydrogenase 314; Alpha Fetoprotein 22; Human Chorionic Gonadotropin 108.
- Day 14: Lactate Dehydrogenase 175; Alpha Fetoprotein 2.4; Human Chorionic Gonadotropin 0.4.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Grandmother; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Grandfather; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAG4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 370 mg.
  Slide TCGA-2G-AAG4-01A-02-TS2: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 23; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-2G-AAG4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAG4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
